Somatic mutation profile of tumor specimen MP2PRT-PAUCXR-TMP1-A (aliquot MP2PRT-PAUCXR-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUCXR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,275 days).
Specimen MP2PRT-PAUCXR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e426a775-9379-4c3b-8f92-06a83a2805cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCXR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCXR-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac33d710-6aa1-495e-bd84-fe4327825f7d

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFPT2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374715499; called by muse, mutect2, varscan2
- MYO1D | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 140/312 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772579154, COSV100555075; called by muse, mutect2, varscan2
- SERPINA9 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 131/354 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs372621576; called by muse, mutect2, varscan2
- TMEM176A | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV50241058; called by muse, mutect2, varscan2
- ADCY10 | c.2805A>T p.K935N | Missense Mutation (SNP) | VAF 180/377 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DYNC1I1 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MTUS1 | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SEMA3A | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR76 | c.1407G>A p.L469= | Splice Region (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- ZNF462 | c.1370A>C p.H457P | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ZSWIM2 | c.866C>A p.A289E | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- ELOA2 | c.42G>T p.L14= | Silent (SNP) | VAF 72/378 reads (19%) | called by muse, mutect2, varscan2
- FGFR3 | c.903C>T p.D301= | Silent (SNP) | VAF 81/310 reads (26%) | catalogued as rs377588489; called by muse, mutect2, varscan2
- KIAA1549 | c.741C>A p.G247= | Silent (SNP) | VAF 15/307 reads (5%) | called by muse, mutect2
- PTGER3 | c.348C>T p.S116= | Silent (SNP) | VAF 235/475 reads (49%) | called by muse, mutect2, varscan2
